Somatic mutation profile of tumor specimen ALCH-B4E8-TTP1-A (aliquot ALCH-B4E8-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4E8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.3 years (26,029 days).
Specimen ALCH-B4E8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e693063-902d-4615-9679-83c9f623328e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4E8-NB1-A (Blood Derived Normal), aliquot ALCH-B4E8-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4244253-96ce-4854-9115-4e6e13afbc99

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 80/574 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 17/246 reads (7%) | catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: pathogenic; called by muse, mutect2
- CXorf38 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100010354; called by muse, mutect2
- DIO3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63774418; called by muse, mutect2
- EPHB2 | c.2914C>T p.Q972* (on ENST00000400191 / NM_001309193.2; = p.Q973* on NM_004442.7) | Nonsense Mutation (SNP) | VAF 16/424 reads (4%) | catalogued as COSV101006732; called by muse, mutect2
- GRIN2A | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58022081, COSV58032220; called by muse, mutect2
- WRN | c.1948A>G p.M650V | Missense Mutation (SNP) | VAF 24/325 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1563348619, COSV53296470; ClinVar: uncertain significance; called by muse, mutect2
- XKR7 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758520075; called by muse, mutect2
- ZNF519 | c.1355G>T p.R452I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.13); catalogued as rs1300556071, COSV73913648; called by muse, mutect2, varscan2
- CEMIP2 | c.3148G>T p.G1050W | Missense Mutation (SNP) | VAF 25/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLPTM1L | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 8/258 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNMBP | c.3357G>C p.K1119N | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GFI1B | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- KRTAP5-6 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2
- MATR3 | c.2057A>G p.D686G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2
- MEN1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- POFUT2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PPP1R37 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- SKP2 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- SPTA1 | c.3865C>G p.Q1289E | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.232); called by muse, mutect2
- TRPM6 | c.3904G>C p.E1302Q | Missense Mutation (SNP) | VAF 17/509 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.289); called by muse, mutect2
- ZMYM6 | c.3025C>T p.H1009Y | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- ADAMTS10 | c.1407G>A p.P469= | Silent (SNP) | VAF 19/438 reads (4%) | catalogued as rs149014496; ClinVar: uncertain significance; called by muse, mutect2
- BCR | c.237C>T p.R79= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- MAP2K2 | c.1080G>C p.L360= | Silent (SNP) | VAF 9/273 reads (3%) | called by muse, mutect2
- WDR19 | c.3898C>T p.L1300= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
